Somatic mutation profile of tumor specimen TCGA-D3-A3MR-06A (aliquot TCGA-D3-A3MR-06A-11D-A21A-08) from TCGA case TCGA-D3-A3MR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 43.0 years (15,695 days).
Specimen TCGA-D3-A3MR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3457c3d5-bdb2-4c51-ba2d-00ec90ffb8e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3MR-10A (Blood Derived Normal), aliquot TCGA-D3-A3MR-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fec601c-4e24-41c9-a9c8-fff7ade1014f

The open-access MAF lists 1,007 somatic variants for this specimen: 648 protein-altering or splice-affecting, 330 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 583, Silent 330, Nonsense Mutation 41, RNA 13, Splice Site 11, Intron 9, Splice Region 7, 5'Flank 5, Frame Shift Del 4, 5'UTR 2, Frame Shift Ins 1, In Frame Del 1.

Variants (750 of 1,007; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FLNC | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as rs755583250, COSV57950044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV66107178; called by muse, mutect2, varscan2
- AASS | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs773718349, COSV62791696; called by muse, mutect2, varscan2
- ABCA13 | c.5041C>T p.Q1681* | Nonsense Mutation (SNP) | VAF 31/190 reads (16%) | catalogued as COSV70043533; called by muse, mutect2, varscan2
- ABCA13 | c.12397G>A p.D4133N | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs749471090, COSV71294003; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCC5 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as COSV55596033; called by muse, mutect2, varscan2
- ABCG1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1331236304, COSV59201136, COSV59210199; called by muse, mutect2, varscan2
- ABL1 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV100584343; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ACSM4 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV68069301; called by muse, mutect2, varscan2
- ACSM4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV68069307; called by muse, mutect2, varscan2
- ADAM22 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55991911, COSV55994568; called by muse, mutect2, varscan2
- ADAM7 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV51541024, COSV51546369; called by muse, mutect2, varscan2
- ADAM7 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51546382; called by muse, mutect2, varscan2
- ADAM7 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867658404, COSV51536214; called by muse, mutect2, varscan2
- ADAMTS10 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs530415046, COSV54359325; called by muse, mutect2
- ADAMTS16 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57006404; called by muse, mutect2
- ADAMTS2 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs372498555; called by muse, mutect2, varscan2
- ADGRG4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs866052593, COSV54949311; called by muse, mutect2, varscan2
- ADSS1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100272359; called by muse, mutect2, varscan2
- AGBL2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100101904; called by muse, mutect2, varscan2
- AGTR2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs1163188247, COSV64156615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHDC1 | c.3473C>A p.A1158D | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.565); catalogued as COSV55942262; called by muse, mutect2, varscan2
- AKNA | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1482740213, COSV56340044; called by muse, mutect2, varscan2
- AKR1C3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV65911151; called by muse, mutect2, varscan2
- ALCAM | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as rs368193586, COSV60254699; called by muse, mutect2, varscan2
- ALMS1 | c.7057T>C p.F2353L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV52521498; called by muse, mutect2, varscan2
- ALPK2 | c.4514C>T p.P1505L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV64496931; called by muse, mutect2, varscan2
- AMFR | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51924221; called by muse, mutect2
- AMIGO1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100881085; called by muse, mutect2
- AMIGO1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100881019; called by muse, mutect2
- ANKRD45 | c.591G>A p.K197= | Splice Region (SNP) | VAF 30/137 reads (22%) | catalogued as COSV100322477, COSV60961393; called by muse, mutect2, varscan2
- ANO10 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52736127; called by muse, mutect2, varscan2
- ANO2 | c.445G>A p.E149K (on ENST00000356134 / NM_001278597.3; = p.E153K on NM_001278596.3) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV59042215; called by muse, mutect2, varscan2
- ANO4 | c.2314G>A p.G772R (on ENST00000392977 / NM_001286615.2; = p.G737R on NM_178826.4) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1290213219, COSV54612652; called by muse, mutect2, varscan2
- ANTXR1 | c.1089G>A p.E363= | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as rs1159917378, COSV58021501; called by muse, mutect2, varscan2
- ANXA1 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs751774481, COSV57412695; called by muse, mutect2, varscan2
- AOX1 | c.3095T>C p.I1032T | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53497150; called by muse, mutect2, varscan2
- AP1G2 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55339674; called by muse, mutect2, varscan2
- APP | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61002662; called by muse, mutect2, varscan2
- ARHGAP17 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51504881; called by muse, mutect2, varscan2
- ARHGEF11 | c.4355C>T p.S1452F | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs770844615, COSV59358421; called by muse, mutect2, varscan2
- ARID2 | c.2680C>T p.Q894* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100535241, COSV57602154; called by muse, mutect2, varscan2
- ARMC12 | c.227C>T p.S76F (on ENST00000373866 / NM_001286574.2; = p.S103F on NM_145028.5) | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55361619; called by muse, mutect2, varscan2
- ARSB | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs945514196, COSV99365230; called by muse, mutect2
- ARSB | c.690G>A p.K230= | Splice Region (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53728929; called by muse, mutect2, varscan2
- ART1 | c.257G>A p.W86* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV51707077; called by muse, mutect2, varscan2
- ASB2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.453); catalogued as rs746405092, COSV60114331; called by muse, mutect2, varscan2
- ASGR2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.229); catalogued as COSV54689963; called by muse, mutect2, varscan2
- ASIC2 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV56764593, COSV56769987; called by muse, mutect2
- ASS1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61688330; called by muse, mutect2, varscan2
- ASXL3 | c.5395C>T p.P1799S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV52478311; called by muse, mutect2, varscan2
- ATP10D | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV56712958; called by muse, mutect2, varscan2
- ATP13A4 | c.3104G>A p.S1035N | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV61326767; called by muse, mutect2, varscan2
- ATP2B1 | c.2447T>A p.I816N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53812564; called by muse, mutect2
- ATP5PF | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53167933; called by muse, mutect2, varscan2
- AXDND1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as COSV62648098; called by muse, mutect2, varscan2
- BCL7B | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 27/169 reads (16%) | catalogued as COSV56271384; called by muse, mutect2, varscan2
- BCORL1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.219); catalogued as COSV54406455; called by muse, mutect2, varscan2
- BICRAL | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs149708370, COSV58408371; called by muse, mutect2, varscan2
- BPTF | c.8198A>G p.N2733S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV58846293; called by muse, mutect2
- BTK | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.83); catalogued as COSV58123590; called by muse, mutect2, varscan2
- BUB1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs773770253, COSV57067181; called by muse, mutect2, varscan2
- BYSL | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV57829630; called by muse, mutect2, varscan2
- C1GALT1 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs781066828, COSV56180404, COSV56180507; called by muse, mutect2, varscan2
- C1orf131 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV59643234; called by muse, mutect2, varscan2
- C2orf16 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV68647031; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- C6orf118 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.595); catalogued as rs1341019160, COSV100024731, COSV57818900; called by muse, mutect2, varscan2
- C8B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as rs1430276829, COSV64779553; called by muse, varscan2
- CACNA1A | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 61/347 reads (18%) | catalogued as COSV64211905; called by muse, mutect2, varscan2
- CACNB4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV52394982; called by muse, mutect2
- CALHM5 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.188); catalogued as COSV62068626; called by muse, mutect2, varscan2
- CAND2 | c.1006+2T>C p.X336_splice (on ENST00000456430 / NM_001162499.2; = p.X243_splice on NM_012298.3) | Splice Site (SNP) | VAF 18/89 reads (20%) | catalogued as COSV55994284; called by muse, mutect2, varscan2
- CAPSL | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1367715056, COSV68438728, COSV68439408; called by muse, mutect2, varscan2
- CATSPER2 | c.1179-4C>T | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100390883; called by mutect2, varscan2
- CCDC141 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs370579684; called by muse, mutect2, varscan2
- CCDC150 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV55878417; called by muse, mutect2, varscan2
- CD163 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV63136965; called by muse, mutect2, varscan2
- CD163 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs1175035496, COSV63136969; called by muse, mutect2, varscan2
- CD248 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV60937780; called by muse, mutect2
- CD40 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 13/94 reads (14%) | catalogued as COSV64848269; called by muse, mutect2, varscan2
- CDCA7 | c.330T>G p.S110R (on ENST00000347703 / NM_145810.3; = p.S189R on NM_031942.5) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60721742; called by muse, mutect2, varscan2
- CDH2 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52295565; called by muse, mutect2, varscan2
- CDH22 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV64839618; called by muse, mutect2, varscan2
- CDK12 | c.275A>C p.D92A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV71002828; called by muse, mutect2
- CDK12 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV101420414, COSV71002115; called by muse, mutect2
- CDYL2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73654928; called by muse, mutect2, varscan2
- CEP250 | c.6277C>T p.H2093Y | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61174167; called by muse, mutect2, varscan2
- CEP350 | c.5312G>A p.R1771K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV62609456; called by muse, mutect2, varscan2
- CERS1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99897422; called by muse, mutect2, varscan2
- CFAP52 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774949333, COSV55349280; called by muse, mutect2, varscan2
- CFHR3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.124); catalogued as COSV66403251, COSV66403349; called by muse, mutect2, varscan2
- CFTR | c.4123C>T p.H1375Y | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as CM087538, COSV50095988; called by muse, mutect2, varscan2
- CHAT | c.698+1G>A p.X233_splice | Splice Site (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100340539; called by muse, mutect2, varscan2
- CHD5 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 34/144 reads (24%) | catalogued as COSV52424393; called by muse, varscan2
- CHD9 | c.8251G>A p.E2751K (on ENST00000398510 / NM_001382353.1; = p.E2735K on NM_025134.7) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.708); catalogued as COSV54616191; called by muse, mutect2, varscan2
- CHODL | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54735271; called by muse, mutect2, varscan2
- CIITA | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV60861927; called by muse, mutect2, varscan2
- CILP2 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV52280211; called by muse, mutect2, varscan2
- CLCA2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65288670; called by muse, mutect2, varscan2
- CLCN1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as rs775412383, COSV100577813, COSV100578293; called by muse, mutect2, varscan2
- CLCN1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); catalogued as COSV100578296; called by muse, mutect2, varscan2
- CLEC4M | c.1077A>T p.E359D | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50224051; called by muse, mutect2, varscan2
- CLK2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs367780359; called by muse, mutect2, varscan2
- CLSTN2 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV71724904; called by muse, mutect2, varscan2
- CLSTN2 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV71724907; called by muse, mutect2, varscan2
- CMYA5 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV71406434; called by muse, mutect2, varscan2
- CNTF | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.681); catalogued as COSV60161824; called by muse, mutect2
- CNTN1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV61645346; called by muse, mutect2, varscan2
- CNTN4 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs548348880, COSV100639315, COSV61868614; called by muse, mutect2, varscan2
- CNTNAP1 | c.4033C>T p.P1345S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV99226754; called by muse, mutect2
- CNTNAP4 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as rs1173355804, COSV56677221, COSV56699281; called by muse, mutect2
- COL11A1 | c.5386G>A p.G1796R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs925433052, COSV62196644; called by muse, mutect2, varscan2
- COL14A1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1256441531, COSV52867728, COSV99920657; called by muse, mutect2, varscan2
- COL17A1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.073); catalogued as COSV62229282; called by muse, mutect2, varscan2
- COL1A2 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99800434; called by muse, mutect2, varscan2
- COL4A1 | c.3851G>A p.G1284E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65431810; called by muse, mutect2, varscan2
- COL4A1 | c.3547G>A p.G1183R | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011261, COSV65431818; called by muse, mutect2
- COL4A1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65431825; called by muse, mutect2
- COL4A4 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.82); catalogued as COSV104395242, COSV61636388; called by muse, mutect2
- COL5A1 | c.5065G>A p.G1689R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV65674418; called by muse, varscan2
- COX7B2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV57222779; called by muse, mutect2, varscan2
- CPD | c.3373C>T p.L1125F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV56716149; called by muse, mutect2, varscan2
- CPNE2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV51964234; called by muse, mutect2, varscan2
- CR1 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1181808330, COSV65462919; called by muse, mutect2
- CR1 | c.5342T>C p.L1781P | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV65462924; called by muse, mutect2, varscan2
- CRB1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1392028577, COSV100957590, COSV66328587; called by muse, mutect2, varscan2
- CREBBP | c.6311G>C p.R2104P | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52138558, COSV52140153; called by muse, mutect2, varscan2
- CRELD2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs915907286, COSV58208411; called by muse, mutect2, varscan2
- CTNNA2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1254632873, COSV63587925; called by muse, mutect2
- CTSV | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as rs1023394620, COSV52345559; called by muse, mutect2, varscan2
- CYP3A5 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV56123053; called by muse, mutect2, varscan2
- CYTIP | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51634797; called by muse, mutect2
- DACT1 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.275); catalogued as rs1423474714, COSV60019827; called by muse, mutect2, varscan2
- DCAF6 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56584938; called by muse, mutect2, varscan2
- DDAH1 | c.732A>T p.E244D | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV52307525; called by muse, mutect2
- DDHD2 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV68158772; called by muse, mutect2, varscan2
- DGKD | c.781C>G p.R261G (on ENST00000264057 / NM_152879.3; = p.R217G on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51041069, COSV51102649; called by muse, mutect2, varscan2
- DGKG | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53972414; called by muse, mutect2, varscan2
- DHRS2 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51634259; called by muse, mutect2, varscan2
- DLC1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV52326898; called by muse, mutect2, varscan2
- DMGDH | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1254126456, COSV54868694; called by muse, mutect2, varscan2
- DNAAF5 | c.906-1G>A p.X302_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52421160; called by muse, mutect2, varscan2
- DNAH17 | c.11708G>A p.G3903E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV67760837; called by muse, mutect2, varscan2
- DNAH8 | c.7504G>A p.V2502M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs749073543, COSV59478850; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2
- DNM3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368300860; called by muse, mutect2, varscan2
- DNMBP | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV60632826; called by muse, mutect2, varscan2
- DOCK4 | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.241); catalogued as COSV69855604; called by muse, mutect2, varscan2
- DOCK9 | c.3704C>T p.P1235L (on ENST00000376460 / NM_001366676.2; = p.P1236L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV59642512; called by muse, mutect2
- DPP10 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); catalogued as COSV59717730, COSV59724769; called by muse, mutect2, varscan2
- DPP6 | c.1373G>A p.G458E (on ENST00000377770 / NM_001364500.2; = p.G396E on NM_001936.5) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100123185, COSV59643596; called by muse, mutect2
- DPYSL5 | c.1589A>C p.E530A | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV56516040; called by muse, mutect2
- DRD2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60762621; called by muse, mutect2, varscan2
- DSEL | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59493187, COSV59494608; called by muse, mutect2, varscan2
- DST | c.19486C>T p.Q6496* (on ENST00000361203 / NM_001374722.1; = p.Q4193* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99758298; called by muse, mutect2
- DST | c.3430C>T p.P1144S (on ENST00000361203 / NM_001374722.1; = p.P818S on NM_001723.6) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV55038832, COSV99755590; called by muse, mutect2, varscan2
- DVL3 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53047405, COSV53050151; called by muse, mutect2, varscan2
- DYNC1I1 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 19/145 reads (13%) | catalogued as COSV61470958; called by muse, mutect2, varscan2
- EGFLAM | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59294209, COSV59301298; called by muse, mutect2, varscan2
- EIF2AK1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV52242989; called by muse, mutect2, varscan2
- ELMO2 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV51686026; called by mutect2, varscan2
- EPHA1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770915770, COSV51976174; called by muse, mutect2, varscan2
- EPHA6 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV101060623, COSV67562008; called by muse, mutect2, varscan2
- EPHA8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756576145, COSV51296296; called by muse, mutect2, varscan2
- EPPK1 | c.5951G>A p.G1984E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV73262350; called by muse, mutect2, varscan2
- EPPK1 | c.4865A>G p.K1622R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV73262351; called by muse, mutect2, varscan2
- ERBB4 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV53551212; called by muse, mutect2, varscan2
- ERICH3 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs754589062, COSV58599602; called by muse, mutect2
- ESPL1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57763151; called by muse, mutect2
- ESR1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779180038, COSV52782036; called by muse, mutect2, varscan2
- EYA4 | c.1030G>A p.D344N (on ENST00000531901 / NM_001301013.1; = p.D338N on NM_004100.5) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV62046197, COSV62060433; called by muse, mutect2, varscan2
- F8 | c.4843G>A p.D1615N | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV64276640, COSV64278416; called by muse, mutect2, varscan2
- FAM184A | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58858633; called by muse, mutect2, varscan2
- FAM76A | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99159494; called by muse, mutect2
- FAM83B | c.1034T>A p.L345* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV60926597; called by muse, mutect2, varscan2
- FAT2 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs769178455, COSV55829016; called by mutect2, varscan2
- FAT3 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.918); catalogued as rs1315776262, COSV53170964; called by muse, mutect2, varscan2
- FAT3 | c.5782G>A p.D1928N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.397); catalogued as COSV53171127; called by muse, mutect2, varscan2
- FBN3 | c.6539G>A p.R2180H | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745383905; called by muse, mutect2
- FBXO15 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV54048564; called by muse, mutect2, varscan2
- FBXW10 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.121); catalogued as COSV57320259; called by muse, mutect2
- FCER1A | c.193T>A p.F65I | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63668393; called by muse, mutect2, varscan2
- FCRL1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63827363; called by muse, mutect2, varscan2
- FCRL5 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1243936761, COSV62511728; called by muse, mutect2, varscan2
- FCRLA | c.409C>T p.R137* (on ENST00000367959; = p.R114* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as rs199798212, COSV99375758; called by muse, mutect2, varscan2
- FER1L5 | c.6107C>T p.P2036L (on ENST00000623019; = p.P2000L on NM_001293083.2) | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1331162131, COSV53843944; called by muse, mutect2
- FGD6 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs751217978, COSV59690883; called by muse, mutect2, varscan2
- FLG2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66173023; called by muse, mutect2, varscan2
- FN1 | c.5884+1G>A p.X1962_splice | Splice Site (SNP) | VAF 11/143 reads (8%) | catalogued as COSV60563767; called by muse, mutect2
- FOXI1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV60389938; called by muse, mutect2, varscan2
- FPR2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs866581731, COSV60672039; called by muse, varscan2
- FRMD3 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58469554; called by muse, mutect2, varscan2
- FRMPD1 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1440146431, COSV66702984; called by muse, mutect2, varscan2
- FUBP1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs569612114, COSV53929392; called by muse, mutect2
- GAB2 | c.1214C>T p.S405F (on ENST00000361507 / NM_080491.3; = p.S367F on NM_012296.3) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60870868; called by muse, mutect2, varscan2
- GABRA1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV50118685; called by muse, varscan2
- GALNT13 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366785930, COSV67231091; called by muse, mutect2
- GATAD2B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs750326578, COSV64083271; called by muse, mutect2, varscan2
- GBP5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as rs779805988, COSV58594294; called by muse, mutect2, varscan2
- GIGYF2 | c.3751C>T p.Q1251* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | catalogued as COSV65253451; called by muse, mutect2
- GIMAP6 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1296601024, COSV61034727; called by muse, mutect2, varscan2
- GIMAP7 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100543710; called by muse, mutect2, varscan2
- GLIPR1L2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57555940; called by muse, mutect2, varscan2
- GLP1R | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV64716372; called by muse, mutect2, varscan2
- GOT1L1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV56877613; called by muse, mutect2
- GPR75 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290691545, COSV61829190; called by muse, mutect2
- GRIN2A | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV100407963, COSV58021001; called by muse, mutect2
- GRIN2B | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74204742, COSV74207697; called by muse, mutect2, varscan2
- GRM7 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63169744; called by muse, mutect2, varscan2
- GRPR | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66669271, COSV66669431; called by muse, mutect2, varscan2
- GSC | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV53077766; called by muse, mutect2, varscan2
- GTF3C1 | c.3944C>T p.S1315F | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62244749; called by muse, mutect2, varscan2
- GTF3C1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV55191337; called by muse, varscan2
- GTPBP10 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV55988879; called by muse, mutect2, varscan2
- GYS2 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53928460; called by muse, mutect2, varscan2
- HBEGF | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs1270676962, COSV50183118; called by muse, mutect2, varscan2
- HCRTR2 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63798982; called by muse, mutect2, varscan2
- HEATR5B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599367, COSV51848925; called by muse, mutect2, varscan2
- HEG1 | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV60765430; called by muse, mutect2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2, varscan2
- HINT3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs772720084, COSV99996210; called by muse, mutect2, varscan2
- HMCN1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54878346; called by muse, mutect2, varscan2
- HNRNPL | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55492718; called by muse, mutect2
- HSD17B4 | c.442C>T p.H148Y (on ENST00000414835 / NM_001199291.3; = p.H123Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56338934; called by mutect2, varscan2
- HSPH1 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV60710124, COSV60713855; called by muse, mutect2, varscan2
- HTRA3 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56471916, COSV56473227; called by muse, mutect2, varscan2
- IDO2 | c.779C>T p.P260L (on ENST00000389060; = p.P273L on NM_194294.2) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100584869; called by muse, mutect2, varscan2
- IGHV1-46 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs562537331; called by muse, mutect2, varscan2
- IGSF10 | c.5155G>A p.G1719R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337745119, COSV56791376; called by muse, mutect2
- IL1RL1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867114006, COSV52119033; called by muse, mutect2
- IL22RA1 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99583169; called by muse, mutect2, varscan2
- IL22RA1 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54630363; called by muse, mutect2
- INTS9 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as COSV68435836; called by muse, mutect2, varscan2
- ITGA4 | c.1523A>C p.E508A | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52003857; called by muse, mutect2
- ITLN1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58275143; called by muse, mutect2, varscan2
- JAKMIP2 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54614924; called by muse, mutect2, varscan2
- JCAD | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs750996746, COSV64758200, COSV64761588; called by muse, mutect2, varscan2
- KCNH5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV59751652; called by muse, mutect2, varscan2
- KCNJ6 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55722750; called by muse, mutect2, varscan2
- KCNQ3 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66473293; called by muse, mutect2, varscan2
- KDM4C | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV67192707; called by muse, mutect2, varscan2
- KEL | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs537228922, COSV62335072; called by muse, mutect2, varscan2
- KIAA0319 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1039035204, COSV65501860; called by muse, mutect2, varscan2
- KIAA2026 | c.5852T>G p.L1951* | Nonsense Mutation (SNP) | VAF 36/118 reads (31%) | catalogued as COSV67357664; called by muse, mutect2, varscan2
- KIF4B | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 19/299 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV70531255; called by muse, mutect2
- KIF5A | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978901860, COSV54051656, COSV54056748; called by muse, mutect2, varscan2
- KMT2B | c.3449C>T p.P1150L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.535); catalogued as COSV55861318; called by mutect2, varscan2
- KNTC1 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV61083960; called by muse, mutect2
- KRTAP10-3 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV59979056; called by muse, mutect2
- LCT | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV51469239; called by muse, mutect2, varscan2
- LDHAL6A | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV52652794; called by muse, mutect2, varscan2
- LDHB | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV63365495; called by muse, mutect2, varscan2
- LEXM | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.135); catalogued as COSV64024140; called by muse, mutect2, varscan2
- LGR6 | c.2588C>T p.S863F (on ENST00000367278 / NM_001017403.1; = p.S811F on NM_021636.3) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368839488; called by muse, mutect2, varscan2
- LHFPL4 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV55004774; called by muse, mutect2, varscan2
- LILRB2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV58748185; called by muse, mutect2, varscan2
- LINGO2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as rs1563845797, COSV58064163; called by muse, mutect2, varscan2
- LMTK2 | c.3661C>T p.R1221C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs754608036, COSV52003549; called by muse, mutect2, varscan2
- LPA | c.4189C>T p.R1397* | Nonsense Mutation (SNP) | VAF 65/289 reads (22%) | catalogued as rs200154828, COSV60299838; called by muse, mutect2, varscan2
- LRG1 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV56705997; called by muse, mutect2, varscan2
- LRIF1 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63898444; called by muse, mutect2, varscan2
- LRP1B | c.13201G>A p.G4401S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67272538; called by muse, mutect2, varscan2
- LY9 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV54435741, COSV54437670; called by muse, varscan2
- LYPD4 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV58028437; called by muse, mutect2, varscan2
- MAGEA11 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV60758633; called by muse, mutect2, varscan2
- MAGEA8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs782267175, COSV54064067; called by muse, mutect2, varscan2
- MAGEB6B | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69689602; called by muse, mutect2, varscan2
- MAGEC1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53580911; called by muse, mutect2, varscan2
- MAGEL2 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV58566732, COSV58569055; called by muse, mutect2, varscan2
- MAGI1 | c.1592C>A p.T531K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100441884, COSV58343744; called by muse, mutect2, varscan2
- MAMDC2 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101015656; called by muse, mutect2, varscan2
- MAP2 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754244309, COSV52307189; called by muse, mutect2, varscan2
- MAP3K21 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs866193751, COSV64042569; called by muse, mutect2, varscan2
- MAPKAPK2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV54318477; called by muse, mutect2, varscan2
- MARCHF10 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV60890324; called by muse, mutect2
- MARCHF11 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.06); catalogued as rs1488229935, COSV60131288; called by muse, mutect2, varscan2
- MATN4 | c.1520C>T p.S507L (on ENST00000372754; = p.S466L on NM_003833.4) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | PolyPhen possibly damaging (0.876); catalogued as rs1301522217, COSV61352054; called by muse, mutect2, varscan2
- MBD4 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51445835; called by muse, mutect2, varscan2
- MBL2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); catalogued as rs1244356396, COSV64758579; called by muse, mutect2, varscan2
- MCM3 | c.2149C>T p.P717S (on ENST00000229854 / NM_001366374.2; = p.P707S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/564 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV57719368; called by muse, mutect2, varscan2
- MCM4 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50632288; called by muse, mutect2, varscan2
- MCM6 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs142938887; called by muse, mutect2, varscan2
- MCMDC2 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100552264, COSV58040794; called by muse, mutect2, varscan2
- MCMDC2 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as rs866259236, COSV58040844; called by muse, mutect2, varscan2
- MCTP2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63294796; called by muse, mutect2
- MEGF8 | c.3781C>T p.R1261W (on ENST00000251268 / NM_001271938.2; = p.R1194W on NM_001410.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs1008783042, COSV52100854; called by muse, mutect2, varscan2
- METTL24 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV58824393; called by muse, mutect2, varscan2
- MGAM | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV71886050; called by muse, mutect2, varscan2
- MMP21 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs766280445, COSV64289583; called by muse, mutect2, varscan2
- MOG | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV65321758; called by muse, mutect2, varscan2
- MORC1 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV51730382; called by muse, mutect2
- MORC1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs372384268, COSV51717687, COSV99225133; called by muse, mutect2, varscan2
- MOV10 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV62492649; called by muse, mutect2
- MRO | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV56498488; called by muse, mutect2, varscan2
- MRPS27 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54653483; called by muse, mutect2
- MSL2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs771996765, COSV53870472; called by muse, mutect2, varscan2
- MTA1 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs781918811, COSV58760293; called by muse, mutect2, varscan2
- MTBP | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.777); catalogued as COSV59966344; called by muse, mutect2, varscan2
- MTCL1 | c.4694C>T p.S1565F (on ENST00000306329 / NM_001378206.1; = p.S1246F on NM_015210.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV60411558; called by muse, mutect2, varscan2
- MTF1 | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV65990601; called by muse, mutect2, varscan2
- MTMR4 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 20/163 reads (12%) | catalogued as COSV60203607; called by muse, mutect2, varscan2
- MUC16 | c.13262C>T p.P4421L | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.352); catalogued as COSV67491864; called by muse, mutect2, varscan2
- MUC16 | c.9325G>A p.E3109K | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67491873; called by muse, mutect2
- MUC16 | c.5072G>A p.R1691K | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs773067737, COSV67491878; called by muse, varscan2
- MUC17 | c.4708G>A p.E1570K | Missense Mutation (SNP) | VAF 88/489 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV60302644; called by muse, mutect2, varscan2
- MUC2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 57/560 reads (10%) | SIFT tolerated, low confidence (0.07); catalogued as rs749265965; called by muse, mutect2
- MYH13 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs1361268933, COSV52842168; called by muse, mutect2, varscan2
- MYO10 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV57029746; called by muse, mutect2, varscan2
- MYO19 | c.2030C>T p.P677L (on ENST00000614623 / NM_001163735.1; = p.P477L on NM_025109.5) | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs773014443; called by muse, mutect2
- MYO3A | c.728C>A p.P243Q | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348402; called by muse, mutect2, varscan2
- MYOM2 | c.3235C>T p.R1079* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | catalogued as rs779920591, COSV50769055; called by muse, mutect2, varscan2
- MYOZ2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV61086183; called by muse, mutect2, varscan2
- MYT1 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs866789769, COSV60508833; called by muse, mutect2, varscan2
- NAGLU | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56796222; called by muse, mutect2, varscan2
- NALCN | c.4352C>T p.S1451F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932714; called by muse, mutect2, varscan2
- NALCN | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1168478003, COSV51964061; called by muse, mutect2
- NCAN | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV53058156; called by muse, mutect2, varscan2
- NEK10 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV58289261; called by muse, mutect2, varscan2
- NES | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV63962869; called by muse, mutect2, varscan2
- NIBAN1 | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV62287558; called by muse, mutect2, varscan2
- NLRP14 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs372852266; called by muse, mutect2, varscan2
- NLRP8 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV52584870; called by muse, mutect2
- NOBOX | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV56197639, COSV99779234; called by muse, mutect2, varscan2
- NOC3L | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as COSV100993358; called by muse, mutect2, varscan2
- NPFFR1 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as COSV53334825; called by muse, mutect2, varscan2
- NPHS1 | c.3665G>A p.G1222E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs771640846, COSV62289805; called by muse, mutect2, varscan2
- NPY1R | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465197647, COSV56716308; called by muse, mutect2, varscan2
- NR4A2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100277300; called by muse, mutect2, varscan2
- NRK | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54606226; called by muse, mutect2, varscan2
- NWD1 | c.4147C>T p.P1383S | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1215413217, COSV60348454; called by muse, mutect2, varscan2
- OBP2B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64402895; called by muse, mutect2, varscan2
- OGDHL | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373960674; called by muse, mutect2, varscan2
- OLFM1 | c.872C>T p.S291F (on ENST00000371793 / NM_001282611.2; = p.S273F on NM_014279.5) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV53282160; called by muse, mutect2, varscan2
- OR10A7 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58278291, COSV58279043; called by muse, varscan2
- OR11A1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65821263; called by muse, mutect2, varscan2
- OR1D5 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73859649; called by muse, mutect2
- OR1L8 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs143007621; called by muse, mutect2, varscan2
- OR1S1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100515484, COSV58708535; called by muse, mutect2, varscan2
- OR2A42 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs781539661, COSV66955668; called by mutect2, varscan2
- OR2B2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1230424278, COSV57580715; called by muse, mutect2, varscan2
- OR2F2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs377438284; called by muse, mutect2
- OR2J3 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65849646; called by muse, varscan2
- OR2J3 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1374320786, COSV65849650; called by muse, varscan2
- OR2M4 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV100140937, COSV60707861; called by muse, mutect2, varscan2
- OR2W3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs747193365, COSV64457957; called by muse, mutect2, varscan2
- OR4K1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs764753465, COSV53461869; called by muse, mutect2
- OR51I1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs377352485, COSV66509192; called by muse, mutect2, varscan2
- OR5B2 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs972126698, COSV56909622; called by muse, mutect2, varscan2
- OR5H1 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100641742; called by muse, mutect2, varscan2
- OR5H2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.315); catalogued as COSV62351836; called by muse, mutect2, varscan2
- OR5L2 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV65725086; called by muse, mutect2, varscan2
- OR5T1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs866744236, COSV57302193; called by muse, mutect2, varscan2
- OR6K3 | c.248C>T p.S83F (on ENST00000368146; = p.S67F on NM_001005327.2) | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63745649; called by muse, mutect2, varscan2
- OR8G2P | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1275814052; called by muse, mutect2, varscan2
- OR8K1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV54404515; called by muse, mutect2
- OSR1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs771434319, COSV55346032; called by muse, mutect2, varscan2
- OTULINL | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1234191456, COSV57036422; called by muse, mutect2, varscan2
- P3H2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV60027562; called by muse, mutect2, varscan2
- PABPC4 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63293349; called by muse, mutect2
- PAPOLB | c.1542A>C p.R514S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV68203449; called by muse, mutect2, varscan2
- PCDH17 | c.2707G>C p.D903H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64978948; called by muse, mutect2, varscan2
- PCDHA13 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV99167635; called by muse, mutect2
- PCDHA13 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); catalogued as COSV56538059; called by muse, mutect2, varscan2
- PCDHA8 | c.1745C>A p.P582Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.293); catalogued as COSV65327429; called by muse, mutect2, varscan2
- PCDHB11 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53383558; called by muse, mutect2, varscan2
- PCDHGA6 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as rs779399493, COSV54027579; called by muse, mutect2, varscan2
- PCLO | c.15371T>G p.L5124R | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61664243; called by muse, mutect2, varscan2
- PCLO | c.12692C>T p.S4231F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV61615595; called by muse, mutect2, varscan2
- PCLO | c.7486G>A p.G2496R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1450683192, COSV61664270; called by muse, mutect2, varscan2
- PDCD2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV51341469; called by muse, mutect2
- PDE3A | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV62982419; called by muse, mutect2, varscan2
- PDE5A | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.523); catalogued as rs374510132; called by muse, mutect2, varscan2
- PEG3 | c.4243G>A p.A1415T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55646821; called by muse, mutect2, varscan2
- PGBD2 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV61400402; called by muse, mutect2, varscan2
- PHF7 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs748850770, COSV59981884; called by muse, varscan2
- PIK3C2G | c.2234G>A p.R745K (on ENST00000676171; = p.R704K on NM_004570.5) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56832712; called by muse, mutect2, varscan2
- PIK3R5 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52650535; called by muse, mutect2, varscan2
- PLA2G4D | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51823410; called by muse, mutect2, varscan2
- PLCB4 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV53817134; called by muse, mutect2, varscan2
- PLCB4 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53796097; called by muse, mutect2, varscan2
- PLCE1 | c.1323C>G p.C441W | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV53371185; called by muse, mutect2, varscan2
- PLCH1 | c.2747G>A p.R916K (on ENST00000340059 / NM_001130960.2; = p.R908K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV58209703; called by muse, mutect2, varscan2
- PLCZ1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56858421; called by muse, mutect2, varscan2
- PLCZ1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV56858445; called by muse, mutect2, varscan2
- PLEKHA4 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377738843; called by mutect2, varscan2
- POLR3C | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61937519; called by muse, mutect2, varscan2
- POU6F2 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs1422798509, COSV68871864; called by muse, mutect2, varscan2
- PPP1R32 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58546073; called by muse, mutect2, varscan2
- PPP1R9A | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56909898; called by muse, mutect2, varscan2
- PRAG1 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1338089311, COSV58166625; called by muse, mutect2, varscan2
- PRAG1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV58159319, COSV58166640; called by muse, mutect2, varscan2
- PRB2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 81/528 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV66984168; called by muse, varscan2
- PRDM10 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58805095; called by muse, mutect2
- PRKCB | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV57800120; called by muse, mutect2, varscan2
- PRKCD | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV57851366; called by muse, mutect2, varscan2
- PRPS1L1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs768761052, COSV72649805; called by muse, mutect2, varscan2
- PRRC2C | c.7103C>T p.S2368F (on ENST00000367742; = p.S2366F on NM_015172.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV58905740; called by muse, mutect2, varscan2
- PRUNE2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.293); catalogued as COSV65028078; called by muse, mutect2, varscan2
- PSG5 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs144866823, COSV61653476; called by muse, mutect2, varscan2
- PSG5 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV61655295; called by muse, mutect2, varscan2
- PSG9 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.491); catalogued as COSV52488305; called by muse, mutect2, varscan2
- PSPH | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV51913668; called by muse, mutect2, varscan2
- PTCH1 | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV59471732, COSV59493294; called by muse, mutect2, varscan2
- PTPRD | c.3157C>T p.L1053F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV61957219, COSV61980299, COSV61985452; called by muse, mutect2, varscan2
- PTPRO | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV55522396; called by muse, mutect2, varscan2
- PTPRT | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV62017760; called by muse, mutect2, varscan2
- PZP | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54370109; called by muse, mutect2, varscan2
- RAB11FIP4 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57932795; called by muse, mutect2, varscan2
- RAB31 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1455992154, COSV71262349; called by muse, mutect2, varscan2
- RABGGTB | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.099); catalogued as COSV60639046; called by muse, mutect2
- RALGPS2 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV61339748; called by muse, mutect2, varscan2
- RAP1GDS1 | c.754G>A p.A252T (on ENST00000408927 / NM_001100427.2; = p.A253T on NM_021159.5) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV52791667; called by muse, mutect2
- RAPGEF1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64700022; called by muse, mutect2, varscan2
- RAPGEF5 | c.406G>A p.E136K (on ENST00000401957 / NM_001367602.2; = p.E439K on NM_012294.5) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59784724; called by muse, mutect2
- RBMXL1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV99556638; called by muse, mutect2, varscan2
- RBMXL1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs375804050, COSV99556641; called by muse, mutect2, varscan2
- RFX4 | c.1717C>T p.P573S (on ENST00000392842 / NM_213594.3; = p.P479S on NM_032491.6) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57572469; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RIMS2 | c.4594C>T p.H1532Y (on ENST00000666250 / NM_001348490.2; = p.H1103Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51668248; called by muse, mutect2, varscan2
- RIT2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267605184, COSV56300970; called by muse, mutect2, varscan2
- RNF103 | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52896951; called by muse, mutect2
- RNF168 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as COSV58839462; called by muse, mutect2, varscan2
- RNF17 | c.1288T>A p.F430I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55050852; called by muse, mutect2, varscan2
- ROBO2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1433821260, COSV59936977; called by muse, mutect2, varscan2
- ROS1 | c.3803T>C p.I1268T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63861443; called by muse, mutect2, varscan2
- RP1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV55126060, COSV99607016; called by muse, mutect2, varscan2
- RP1L1 | c.4148G>A p.G1383E | Missense Mutation (SNP) | VAF 72/443 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs200849023, COSV101223437; called by muse, mutect2, varscan2
- RP1L1 | c.4147G>A p.G1383R | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1241200968, COSV101223438; called by muse, mutect2, varscan2
- RP1L1 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1563124453, COSV66751946, COSV66759982; called by muse, mutect2, varscan2
- RP1L1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764590042, COSV61445282; called by muse, mutect2, varscan2
- RPL29 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV53686462; called by muse, mutect2, varscan2
- RPRD1A | c.486G>A p.Q162= | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59823182; called by muse, mutect2, varscan2
- RPTN | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 241/1415 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100285627; called by muse, mutect2, varscan2
- RTL3 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1434702051, COSV58185787, COSV58186172; called by muse, mutect2, varscan2
- RYR1 | c.11155G>A p.D3719N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62110175; called by muse, mutect2, varscan2
- SACS | c.8545C>T p.P2849S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV66546583; called by muse, mutect2, varscan2
- SAFB | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52653885; called by muse, mutect2, varscan2
- SAMD11 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1348392674, COSV58990853; called by muse, mutect2, varscan2
- SAMHD1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV99484212; called by muse, mutect2, varscan2
- SARS1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV52323140; called by muse, mutect2, varscan2
- SCGB1A1 | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV53474028; called by muse, mutect2, varscan2
- SCN11A | c.4287G>A p.W1429* | Nonsense Mutation (SNP) | VAF 27/177 reads (15%) | catalogued as COSV56568045, COSV56578038; called by muse, mutect2, varscan2
- SDK1 | c.3713C>T p.T1238I | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1562830504, COSV67387903; called by muse, mutect2, varscan2
- SEC16A | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs746434732, COSV51540275; called by muse, mutect2, varscan2
- SELENBP1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as rs1180847682, COSV100923670; called by muse, mutect2, varscan2
- SELPLG | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57314411, COSV57314896; called by muse, mutect2, varscan2
- SEPTIN14 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs748203186, COSV101193393; called by muse, mutect2, varscan2
- SERPINB11 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs1254435404, COSV66957790; called by muse, mutect2, varscan2
- SERPINB8 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54640605; called by muse, mutect2, varscan2
- SERPINI1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55507755; called by muse, mutect2, varscan2
- SFSWAP | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55525674; called by muse, mutect2, varscan2
- SGCE | c.1443-1G>A p.X481_splice (on ENST00000647096; = p.X418_splice on NM_003919.3) | Splice Site (SNP) | VAF 29/159 reads (18%) | catalogued as COSV99722765; called by muse, mutect2, varscan2
- SGSM3 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV50655256; called by muse, mutect2, varscan2
- SH3BP5 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53745833; called by muse, mutect2, varscan2
- SH3RF3 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1166098234, COSV58695005; called by muse, mutect2, varscan2
- SHANK1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV53261705; called by muse, mutect2
- SI | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52300031; called by muse, mutect2, varscan2
- SIGLEC1 | c.1165T>A p.F389I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV52472085; called by muse, mutect2, varscan2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by muse, mutect2, varscan2
- SLC14A2 | c.1244A>T p.N415I | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV54914322; called by muse, mutect2, varscan2
- SLC15A2 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV55200857; called by muse, mutect2, varscan2
- SLC15A3 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV50021688; called by muse, mutect2, varscan2
- SLC22A6 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as COSV64561029; called by muse, mutect2
- SLC26A11 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100755422; called by muse, mutect2, varscan2
- SLC26A3 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.868); catalogued as rs923181529, COSV60640273; called by muse, mutect2, varscan2
- SLC2A3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.327); catalogued as COSV50007592; called by muse, mutect2, varscan2
- SLC2A4RG | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55514696; called by muse, mutect2
- SLC33A1 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV63947736; called by muse, mutect2, varscan2
- SLC44A2 | c.2012T>C p.F671S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59838905; called by muse, mutect2, varscan2
- SLC4A8 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV60657985; called by muse, mutect2, varscan2
- SLC6A20 | c.261C>T p.V87= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs141869919; called by muse, mutect2, varscan2
- SLC7A4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as rs550001213, COSV60386032; called by muse, mutect2, varscan2
- SLFN13 | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV53195524; called by muse, mutect2
- SLIT1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs779883726, COSV56598758; called by muse, mutect2, varscan2
- SLX4 | c.4382C>T p.A1461V | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs1186678343, COSV53561374; called by muse, mutect2, varscan2
- SMARCC1 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as COSV54386449; called by muse, mutect2, varscan2
- SMG1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV67174746; called by muse, mutect2, varscan2
- SMG8 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.329); catalogued as COSV99958953; called by muse, mutect2, varscan2
- SMPDL3B | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV65855314; called by muse, mutect2
- SNAP91 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs771532118, COSV52133754; called by muse, mutect2, varscan2
- SNTG1 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52470968; called by muse, mutect2, varscan2
- SNTG1 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52435365, COSV52470989; called by muse, mutect2, varscan2
- SOHLH2 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1265089671, COSV101157961; called by muse, mutect2
- SORL1 | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 81/659 reads (12%) | catalogued as COSV52762227; called by muse, mutect2, varscan2
- SOX5 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as COSV58633088; called by muse, mutect2, varscan2
- SPACA3 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.562); catalogued as COSV52192602; called by muse, mutect2, varscan2
- SPAG1 | c.14A>C p.D5A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV52563337; called by muse, mutect2, varscan2
- SPAG17 | c.5157G>A p.W1719* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | catalogued as COSV60467995; called by muse, mutect2
- SPATA31D1 | c.4586C>T p.P1529L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1306579015; called by muse, mutect2
- SPATA31E1 | c.3170C>T p.S1057L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as rs145805743, COSV57795005; called by muse, mutect2, varscan2
- SPOCD1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99930118; called by muse, mutect2, varscan2
- SPOCD1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99930121; called by muse, mutect2, varscan2
- SPTA1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV63753714; called by muse, mutect2, varscan2
- SPTB | c.5144C>T p.S1715F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67634868; called by muse, mutect2, varscan2
- SRCAP | c.2104C>A p.Q702K | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV52680507; called by muse, mutect2
- SRCIN1 | c.2728G>A p.G910R (on ENST00000621492; = p.G876R on NM_025248.3) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs533940451; called by muse, mutect2, varscan2
- SRSF5 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.388); catalogued as rs1374126988, COSV67936894, COSV67937258; called by muse, mutect2, varscan2
- ST18 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52508620; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | PolyPhen probably damaging (0.982); catalogued as rs761180303, COSV59572003; called by muse, mutect2, varscan2
- STAB1 | c.7484G>A p.G2495E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58742751; called by muse, mutect2
- STARD13 | c.1721T>G p.V574G (on ENST00000336934 / NM_001243476.3; = p.V456G on NM_052851.3) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55236341; called by muse, mutect2, varscan2
- STC1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs1260045910, COSV51688609; called by muse, mutect2, varscan2
- STK31 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63457505; called by muse, mutect2, varscan2
- STMN4 | c.188C>T p.S63F (on ENST00000265770 / NM_001283054.2; = p.S90F on NM_030795.4) | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs267601878, COSV56108363; called by muse, mutect2, varscan2
- STON1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs144911860, COSV59132866; called by muse, mutect2, varscan2
- STOX2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200674735; called by muse, mutect2, varscan2
- STS | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV54271893; called by muse, mutect2, varscan2
- STXBP6 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as COSV60597811; called by muse, mutect2, varscan2
- SULT1E1 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV56948750; called by muse, mutect2, varscan2
- SYCP2L | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV51657387; called by muse, mutect2, varscan2
- SYNE1 | c.13126C>T p.P4376S (on ENST00000367255 / NM_182961.4; = p.P4305S on NM_033071.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99572679; called by muse, mutect2, varscan2
- SYNE1 | c.6446G>A p.G2149E (on ENST00000367255 / NM_182961.4; = p.G2156E on NM_033071.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV55096064; called by muse, mutect2, varscan2
- SYNJ1 | c.4271C>T p.S1424F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV59156296; called by muse, varscan2
- SYT1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54049842; called by muse, mutect2, varscan2
- SYT6 | c.273G>T p.K91N (on ENST00000610222 / NM_001366225.1; = p.K6N on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV65776040; called by muse, mutect2
- TARBP1 | c.4243+1G>A p.X1415_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as rs768819942, COSV50188062; called by mutect2, varscan2
- TAS2R9 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.889); catalogued as rs115762530, COSV53690494; called by muse, mutect2
- TASOR | c.3247G>C p.D1083H (on ENST00000355628 / NM_001365636.2; = p.D707H on NM_015224.3) | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100843698, COSV62929668; called by muse, mutect2, varscan2
- TBC1D22A | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61445833; called by muse, mutect2, varscan2
- TBC1D9 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs199939470, COSV71308850; called by muse, mutect2, varscan2
- TBX22 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100960729, COSV64785115; called by muse, mutect2, varscan2
- TCIM | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs758408259, COSV59927620; called by muse, mutect2, varscan2
- TDRD5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1262356071, COSV54239510; called by muse, mutect2, varscan2
- TEFM | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58978725; called by muse, mutect2, varscan2
- TEK | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV66234240; called by muse, mutect2, varscan2
- TEK | c.1517A>T p.Y506F | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66234252; called by muse, mutect2, varscan2
- TENM1 | c.5422G>A p.G1808R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV64442285; called by muse, mutect2, varscan2
- TENM3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV69308897; called by muse, mutect2, varscan2
- TENM3 | c.6644G>A p.R2215Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs765868760, COSV69308746; called by muse, mutect2, varscan2
- TEPSIN | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV56144803; called by muse, mutect2
- TET1 | c.6142T>C p.F2048L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV65389372; called by muse, mutect2, varscan2
- TEX101 | c.184G>A p.E62K (on ENST00000598265 / NM_001130011.3; = p.E80K on NM_031451.4) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53663083; called by muse, mutect2, varscan2
- TF | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV53919202, COSV99396156; called by muse, mutect2, varscan2
- TGM4 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV56094328; called by muse, mutect2, varscan2
- THNSL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs964320373, COSV59084671; called by muse, mutect2, varscan2
- THSD7B | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV55735218; called by muse, mutect2, varscan2
- TIE1 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV65251326; called by muse, mutect2, varscan2
- TIMD4 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV50859987; called by muse, mutect2, varscan2
- TIMD4 | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50860020; called by muse, mutect2, varscan2
- TMC7 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as COSV58587700; called by muse, mutect2, varscan2
- TMEM178A | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56143368; called by muse, mutect2, varscan2
- TMPO | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100587811; called by muse, mutect2, varscan2
- TMPO | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100587812; called by muse, mutect2, varscan2
- TNFRSF19 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50320358; called by muse, mutect2, varscan2
- TPST1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59180506; called by muse, mutect2, varscan2
- TRAF6 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV61923599; called by muse, mutect2, varscan2
- TRIM11 | c.507G>A p.K169= | Splice Region (SNP) | VAF 8/69 reads (12%) | catalogued as COSV52860009; called by muse, mutect2
- TRIM35 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV57765666; called by muse, mutect2, varscan2
- TRIM45 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56712802; called by muse, mutect2, varscan2
- TRIM9 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046089753, COSV53624605; called by muse, mutect2, varscan2
- TRIP12 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99390683; called by muse, mutect2, varscan2
- TRPC1 | c.1633C>T p.L545F (on ENST00000476941 / NM_001251845.2; = p.L511F on NM_003304.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.714); catalogued as COSV56429883; called by muse, mutect2, varscan2
- TSC22D4 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.406); catalogued as rs754493931, COSV55724726; called by muse, mutect2, varscan2
- TSHZ2 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61591401; called by muse, mutect2, varscan2
- TTLL3 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); catalogued as COSV59615806; called by muse, mutect2, varscan2
- TTN | c.89359C>T p.R29787C (on ENST00000591111; = p.R22363C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/142 reads (11%) | PolyPhen probably damaging (0.973); catalogued as rs190282707, COSV60246356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.66272G>A p.G22091E (on ENST00000591111; = p.G14667E on NM_003319.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV60333055; called by muse, mutect2
- TTN | c.50940G>A p.W16980* (on ENST00000591111; = p.W9556* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/143 reads (6%) | catalogued as COSV100621594; called by muse, mutect2
- TTN | c.50939G>A p.W16980* (on ENST00000591111; = p.W9556* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV100621595; called by muse, mutect2
- TTN | c.43216G>A p.E14406K (on ENST00000591111; = p.E6982K on NM_003319.4) | Missense Mutation (SNP) | VAF 21/184 reads (11%) | PolyPhen possibly damaging (0.84); catalogued as COSV59863108; called by muse, mutect2, varscan2
- TTN | c.40306G>A p.E13436K (on ENST00000591111; = p.E6012K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | PolyPhen possibly damaging (0.894); catalogued as COSV59890889; called by muse, mutect2
- TTN | c.40049C>T p.S13350F (on ENST00000591111; = p.S5926F on NM_003319.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen possibly damaging (0.804); catalogued as COSV100621600; called by mutect2, varscan2
- TTN | c.33196G>A p.E11066K (on ENST00000591111; = p.E10139K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | PolyPhen benign (0.053); catalogued as COSV60230256; called by muse, varscan2
- TTN | c.32326G>A p.E10776K (on ENST00000591111; = p.E9849K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | PolyPhen probably damaging (0.991); catalogued as rs1223983021, COSV59862637; called by muse, mutect2
- TTN | c.23311G>A p.E7771K (on ENST00000591111; = p.E6844K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.311); catalogued as rs1359281047, COSV59908383; called by muse, mutect2
- TXLNB | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs199860574, COSV64445018, COSV64446028; called by muse, mutect2, varscan2
- UBAP2L | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | catalogued as COSV55180797; called by muse, mutect2, varscan2
- UBR4 | c.8366C>T p.P2789L | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64398903; called by muse, mutect2
- UGT1A3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs762751427, COSV100530581; called by muse, mutect2, varscan2
- UPF2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100707509, COSV62663718; called by mutect2, varscan2
- USH1C | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770543827, CM140365, COSV50034713; ClinVar: uncertain significance; called by mutect2, varscan2
- USH2A | c.7795C>T p.Q2599* | Nonsense Mutation (SNP) | VAF 25/138 reads (18%) | catalogued as COSV56432114; called by muse, mutect2, varscan2
- UTP20 | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV55385026; called by muse, mutect2
- VCAM1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54121849; called by muse, mutect2, varscan2
- VIM | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs747904058, COSV56407686; called by muse, mutect2, varscan2
- VSNL1 | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV54603431; called by muse, mutect2
- VWF | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54633465; called by muse, mutect2, varscan2
- WASL | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56132814; called by muse, mutect2, varscan2
- WDR49 | c.1397C>T p.T466I (on ENST00000308378 / NM_001366158.1; = p.T807I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV57717444; called by muse, mutect2, varscan2
- WDR72 | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV64753764; called by muse, mutect2, varscan2
- WDR76 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs781465373, COSV55476756; called by muse, mutect2, varscan2
- WNT2B | c.584G>A p.G195D (on ENST00000369684 / NM_024494.3; = p.G176D on NM_004185.4) | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56671940; called by muse, mutect2, varscan2
- WSB2 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV59575031; called by muse, mutect2, varscan2
- XIRP1 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61140929; called by muse, varscan2
- XIRP1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs145798293; called by muse, mutect2, varscan2
- XIRP2 | c.6308C>T p.P2103L (on ENST00000628543; = p.P2278L on NM_152381.6) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV54732780; called by muse, mutect2, varscan2
- XPO6 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV58971377; called by muse, mutect2
- XRCC1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53452811; called by muse, mutect2, varscan2
- XRN1 | c.4994C>T p.S1665F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV53813945, COSV53817928; called by muse, mutect2, varscan2
- XRRA1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV58500340; called by muse, mutect2, varscan2
- YBX2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1247615491, COSV50301842, COSV50302313; called by muse, mutect2, varscan2
- YLPM1 | c.6307G>A p.D2103N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57825397; called by muse, mutect2, varscan2
- ZBTB38 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV58544101; called by muse, mutect2, varscan2
- ZBTB4 | c.2453C>A p.A818D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV60140015, COSV60142272; called by muse, mutect2, varscan2
- ZFHX4 | c.8740G>A p.G2914R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50692431; called by mutect2, varscan2
- ZFHX4 | c.9715G>A p.D3239N | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1227663100, COSV50642938, COSV50846359; called by muse, mutect2, varscan2
- ZFHX4 | c.10834G>A p.D3612N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV50666852; called by muse, mutect2
- ZFP64 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53803673; called by muse, mutect2, varscan2
- ZFPM2 | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); catalogued as COSV65875761; called by muse, mutect2, varscan2
- ZFPM2 | c.3043C>T p.P1015S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.027); catalogued as COSV65875766; called by muse, mutect2, varscan2
- ZIM2 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV55646784; called by muse, mutect2
- ZIM2 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55646796; called by muse, mutect2, varscan2
- ZKSCAN3 | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52854353; called by muse, mutect2, varscan2
- ZMYND8 | c.3123G>A p.W1041* (on ENST00000311275 / NM_001363741.2; = p.W1015* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/288 reads (23%) | catalogued as COSV53696028; called by muse, mutect2, varscan2
- ZNF296 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55519184; called by muse, mutect2, varscan2
- ZNF331 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs770166196, COSV53474358; called by muse, mutect2, varscan2
- ZNF331 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs143007880; called by muse, mutect2, varscan2
- ZNF33B | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 31/260 reads (12%) | catalogued as COSV63943381; called by muse, mutect2, varscan2
- ZNF354A | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59984883; called by muse, mutect2
- ZNF395 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60430320; called by muse, mutect2, varscan2
- ZNF419 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.827); catalogued as COSV55663015; called by mutect2, varscan2
- ZNF438 | c.1726_1729del p.F576Afs*10 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | catalogued as rs745841672; called by mutect2, pindel, varscan2
- ZNF445 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1469964326, COSV68539600; called by muse, mutect2, varscan2
- ZNF451 | c.1112T>C p.F371S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV62599936; called by muse, varscan2
- ZNF474 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1307212570, COSV56947587; called by muse, mutect2, varscan2
- ZNF479 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58642760; called by muse, mutect2, varscan2
- ZNF534 | c.368G>A p.G123E (on ENST00000332323 / NM_001143939.3; = p.G110E on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs776877897, COSV56520802, COSV56521770; called by muse, mutect2, varscan2
- ZNF662 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60242995; called by muse, mutect2, varscan2
- ZNF676 | c.1201G>A p.G401R (on ENST00000650058; = p.G369R on NM_001001411.3) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs759129494, COSV68094278; called by muse, mutect2, varscan2
- ZNF831 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV64045012; called by muse, mutect2, varscan2
- ZNF93 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59378614; called by muse, mutect2, varscan2
- ZSCAN29 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101212222; called by muse, mutect2
- ZSCAN4 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV56595011; called by muse, mutect2, varscan2
- ZSWIM2 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54579305; called by muse, mutect2
- ACSM2A | c.1171G>A p.D391N (on ENST00000219054; = p.D312N on NM_001308169.2) | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2
- ADAM22 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.370_371delinsT p.P124Sfs*5 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2*
- CFAP47 | c.4682_4687del p.T1561_I1562del | In Frame Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel
- CHRAC1 | c.331_332del p.K111Efs*5 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- CWC25 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); called by muse, mutect2
- FCGBP | c.11557C>G p.R3853G | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KIR3DL3 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- MAGEB6B | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MUC3A | c.9162G>A p.W3054* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- NEK9 | c.1328-20_1350del p.X443_splice | Splice Site (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- OR4F5 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR51S1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PRAMEF15 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 68/1560 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- SPANXB1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TP53I3 | c.618del p.G207Vfs*8 | Frame Shift Del (DEL) | VAF 30/310 reads (10%) | called by mutect2, pindel
- TRAV12-2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- VEZF1 | c.312dup p.P105Afs*46 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | called by pindel, varscan2
- A4GALT | c.666C>T p.A222= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV50746120; called by muse, mutect2
- AADAC | c.624C>T p.V208= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV51761336; called by muse, mutect2, varscan2
- ABCA1 | c.2244C>T p.A748= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs534710743, COSV66070360; called by muse, mutect2, varscan2
- ABCA3 | c.660G>A p.R220= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV57059656, COSV57061278; called by muse, mutect2, varscan2
- ABCC10 | c.2040C>T p.I680= (on ENST00000372530 / NM_001198934.2; = p.I652= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV55093733; called by muse, mutect2, varscan2
- ABCC6 | c.3114G>A p.R1038= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs1475667555, COSV52747658; called by muse, mutect2, varscan2
- ABCC8 | c.969C>T p.I323= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs748659098, COSV56850831; called by muse, mutect2, varscan2
- ABCG4 | c.1308C>T p.F436= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs371249807; called by mutect2, varscan2
- ABL1 | c.2523C>T p.A841= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1564324119, COSV100584350; called by muse, mutect2, varscan2
- ABLIM3 | c.687C>T p.Y229= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV58648441; called by muse, mutect2, varscan2
- ACOXL | c.816G>A p.K272= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV67738314; called by muse, mutect2, varscan2
- ACP3 | c.918C>T p.L306= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as rs752691820, COSV60487832; called by muse, mutect2, varscan2
- ACSM1 | c.312G>A p.Q104= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV54639936; called by muse, mutect2, varscan2
- ACTL6B | c.1083C>T p.L361= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as COSV50518372; called by muse, mutect2
- ADGRB2 | c.2172C>T p.I724= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV57078598; called by muse, mutect2
- ADGRV1 | c.15909C>T p.F5303= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs754492973, COSV67994856; called by muse, mutect2, varscan2
- ADIPOQ | c.246A>G p.E82= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV57860010; called by muse, mutect2, varscan2
- ADSS1 | c.1275G>A p.Q425= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1258092945, COSV100272357; called by muse, mutect2, varscan2
- AICDA | c.186C>T p.L62= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV57563546; called by muse, mutect2, varscan2
- ALB | c.1725C>T p.F575= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs1283552159, COSV55737718, COSV55742116; called by muse, mutect2, varscan2
- AMER3 | c.1761G>A p.G587= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs769755962, COSV58469883; called by muse, mutect2, varscan2
- ANK1 | c.1992G>A p.G664= | Silent (SNP) | VAF 37/288 reads (13%) | catalogued as COSV55881911; called by muse, mutect2, varscan2
- APBA1 | c.2052C>T p.I684= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV55237177; called by muse, mutect2, varscan2
- ARHGAP30 | c.1296G>A p.P432= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs539740244, COSV63514799; called by muse, mutect2, varscan2
- ARHGEF11 | c.1104C>T p.F368= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs36029227; called by muse, mutect2, varscan2
- ASIC1 | c.774C>T p.I258= | Silent (SNP) | VAF 40/247 reads (16%) | catalogued as rs377151596; called by muse, mutect2, varscan2
- ATG2B | c.4536C>T p.I1512= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs866546118, COSV55892045; called by muse, mutect2, varscan2
- ATP13A4 | c.600G>A p.K200= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV55074950; called by muse, mutect2, varscan2
- ATP1A3 | c.813C>T p.G271= (on ENST00000545399 / NM_001256214.2; = p.G258= on NM_152296.5) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV57488250; called by muse, mutect2, varscan2
- ATP8B3 | c.2211C>T p.I737= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs777784131, COSV59548348; called by muse, mutect2, varscan2
- BAHCC1 | c.6597C>T p.F2199= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs782325112, COSV57027031; called by muse, mutect2
- BCAS3 | c.1296C>T p.F432= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV66781783; called by muse, mutect2, varscan2
- BDH1 | c.801C>T p.V267= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs183131131, COSV64019794; called by muse, mutect2, varscan2
- BNIP5 | c.1785C>T p.N595= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV71325838; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- BRINP1 | c.888T>C p.S296= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV56312638; called by muse, mutect2, varscan2
- BSDC1 | c.708A>T p.P236= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV61983366; called by muse, mutect2, varscan2
- CACNA1C | c.1752C>T p.F584= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs886043677, COSV59694388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.2778C>T p.F926= (on ENST00000350061 / NM_001128840.3; = p.F946= on NM_000720.4) | Silent (SNP) | VAF 45/243 reads (19%) | catalogued as COSV55464147; called by muse, mutect2, varscan2
- CACNG7 | c.756C>T p.I252= | Silent (SNP) | VAF 68/319 reads (21%) | catalogued as COSV55816765; called by muse, varscan2
- CADPS2 | c.882C>T p.P294= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV57384824; called by muse, mutect2
- CALN1 | c.447G>A p.T149= (on ENST00000329008 / NM_001017440.3; = p.T191= on NM_031468.4) | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as rs766714139, COSV61119273; called by muse, mutect2, varscan2
- CARD14 | c.264C>T p.F88= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60126635; called by muse, mutect2, varscan2
- CATSPERG | c.3204C>T p.F1068= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53053357; called by muse, mutect2, varscan2
- CBX5 | c.21G>A p.R7= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV52938682; called by muse, mutect2, varscan2
- CCDC116 | c.574C>T p.L192= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV53038725; called by muse, mutect2, varscan2
- CCIN | c.744C>T p.S248= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV58725607; called by muse, mutect2, varscan2
- CCL3L3 | c.246C>T p.V82= | Silent (SNP) | VAF 30/408 reads (7%) | called by muse, mutect2
- CD177 | c.441A>C p.T147= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV65121351; called by muse, mutect2
- CD1C | c.645C>T p.S215= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV63807618; called by muse, mutect2, varscan2
- CD1E | c.807C>T p.L269= | Silent (SNP) | VAF 46/259 reads (18%) | catalogued as COSV63772802; called by muse, mutect2, varscan2
- CDH10 | c.2133G>A p.R711= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs1036386867, COSV100050439, COSV52588107; called by muse, mutect2
- CDH16 | c.1968C>T p.F656= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV55339539; called by muse, mutect2
- CDH23 | c.5037C>T p.I1679= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs757049933, COSV56488489; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CELA2A | c.750C>T p.S250= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs1166338276, COSV100657524, COSV62747524; called by muse, mutect2
- CELF6 | c.1254C>T p.P418= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as COSV54718837; called by muse, mutect2, varscan2
- CENPE | c.2229C>T p.V743= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV54389787; called by muse, mutect2, varscan2
- CERS1 | c.462C>T p.L154= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99897425; called by muse, mutect2, varscan2
- CFAP47 | c.5328C>T p.I1776= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1414813902, COSV57976019; called by muse, mutect2, varscan2
- CFAP53 | c.1461C>T p.V487= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV68352860; called by muse, mutect2, varscan2
- CGREF1 | c.240C>T p.L80= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs757668558, COSV53151896; called by mutect2, varscan2
- CHRD | c.1923C>T p.L641= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV52612291; called by muse, mutect2, varscan2
- CHRNB1 | c.1203C>T p.F401= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV60142268; called by muse, mutect2, varscan2
- CHRNG | c.630C>T p.H210= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV101263990; called by muse, mutect2, varscan2
- CHST1 | c.537G>A p.G179= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100346387; called by muse, mutect2
- CNGA2 | c.517C>T p.L173= | Silent (SNP) | VAF 80/210 reads (38%) | catalogued as COSV61706232; called by muse, mutect2, varscan2
- CNTNAP3 | c.1569G>A p.A523= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs772381332, COSV99905271; called by muse, mutect2, varscan2
- CNTROB | c.2574C>T p.I858= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs142142775; called by muse, mutect2, varscan2
- COL11A1 | c.2571C>T p.F857= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV62188732; called by muse, mutect2, varscan2
- COL17A1 | c.1539G>A p.G513= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as COSV62229287; called by muse, mutect2, varscan2
- COL1A2 | c.1743C>T p.L581= | Silent (SNP) | VAF 42/262 reads (16%) | catalogued as COSV99800431; called by muse, mutect2, varscan2
- COL21A1 | c.2646G>A p.G882= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV55179002; called by muse, mutect2, varscan2
- COL6A6 | c.3390C>T p.I1130= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs760211433, COSV62024612; called by muse, mutect2, varscan2
- CPA4 | c.1242G>A p.E414= | Silent (SNP) | VAF 42/256 reads (16%) | catalogued as COSV55984961; called by muse, mutect2, varscan2
- CPPED1 | c.475C>T p.L159= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99903419; called by muse, mutect2, varscan2
- CSMD2 | c.1893C>T p.F631= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV53886957; called by muse, mutect2
- CSRNP3 | c.87C>T p.S29= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs1558944654, COSV58785397; called by muse, mutect2, varscan2
- CST11 | c.34C>T p.L12= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs781161436, COSV100776871, COSV100776873; called by mutect2, varscan2
- CTNNA2 | c.906C>T p.S302= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100785326; called by muse, mutect2
- CYB5RL | c.597C>T p.I199= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55279324; called by muse, mutect2, varscan2
- CYFIP2 | c.3471C>T p.A1157= (on ENST00000616178 / NM_001291722.2; = p.A1132= on NM_014376.4) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59050148; called by muse, mutect2, varscan2
- CYP11A1 | c.1497C>T p.L499= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs376403897, COSV51432226; called by muse, mutect2, varscan2
- CYP19A1 | c.795G>A p.R265= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as rs141974163; called by muse, mutect2, varscan2
- CYP4A11 | c.849C>T p.I283= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as COSV60225534; called by muse, mutect2
- DDX27 | c.1317C>T p.F439= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV65610639; called by muse, mutect2, varscan2
- DISP3 | c.708C>T p.I236= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53837038; called by muse, mutect2, varscan2
- DNAH1 | c.5961C>T p.F1987= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs61753444, COSV70235803; called by muse, mutect2, varscan2
- DNAH17 | c.12057G>A p.K4019= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV67760833; called by muse, mutect2, varscan2
- DPYSL2 | c.1215C>T p.S405= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs757945823, COSV60785183; called by muse, mutect2, varscan2
- DST | c.19485C>T p.L6495= (on ENST00000361203 / NM_001374722.1; = p.L4192= on NM_015548.5) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99758300; called by muse, mutect2
- DYSF | c.5196G>A p.E1732= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV50569183; called by muse, mutect2, varscan2
- DZIP3 | c.243C>T p.S81= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV64313781; called by muse, mutect2, varscan2
- EFCAB5 | c.3054G>A p.K1018= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV57937060; called by muse, mutect2, varscan2
- ENOX2 | c.1287G>A p.R429= (on ENST00000338144 / NM_001382520.1; = p.R400= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV57657827; called by muse, mutect2, varscan2
- ENTPD8 | c.96C>T p.A32= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58163646; called by muse, mutect2, varscan2
- EPHA4 | c.2808T>C p.G936= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV56043753; called by muse, mutect2, varscan2
- EPHB1 | c.2817C>T p.S939= | Silent (SNP) | VAF 30/223 reads (13%) | catalogued as rs1400901643, COSV67656718; called by muse, mutect2, varscan2
- EPHB4 | c.2067C>T p.V689= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV62270473; called by muse, mutect2, varscan2
- EPHB6 | c.240C>T p.A80= | Silent (SNP) | VAF 71/418 reads (17%) | catalogued as COSV67420723; called by muse, mutect2, varscan2
- EPHB6 | c.2433G>A p.K811= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV63893579; called by muse, mutect2, varscan2
- EPPK1 | c.2268C>T p.I756= | Silent (SNP) | VAF 25/174 reads (14%) | catalogued as COSV73262352; called by muse, mutect2, varscan2
- F5 | c.4914A>G p.E1638= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV63128090; called by muse, mutect2, varscan2
257 further variants in this file (0 protein-altering or splice-affecting, 228 silent, 29 other) are not listed here.
